Somatic mutation profile of tumor specimen TCGA-ET-A40T-01A (aliquot TCGA-ET-A40T-01A-11D-A23M-08) from TCGA case TCGA-ET-A40T, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 26.1 years (9,531 days).
Specimen TCGA-ET-A40T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1177dc18-429d-42ab-8d02-4a32c4c496ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A40T-10A (Blood Derived Normal), aliquot TCGA-ET-A40T-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/331fc209-f254-47b4-820e-0ff588f54ba1

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO3 | c.475G>C p.D159H | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99881109; called by muse, mutect2
- ATP2B3 | c.1393G>C p.G465R | Missense Mutation (SNP) | VAF 37/513 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV99683280; called by muse, mutect2
- H4C7 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as rs967059166, COSV55100414, COSV55100792; called by muse, mutect2, varscan2
- RBFA | c.34C>G p.R12G | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100080103, COSV51535661; called by muse, mutect2
- SRGAP1 | c.1696G>A p.D566N | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV100754346; called by muse, mutect2, varscan2
- TDRD7 | c.1451G>A p.G484D | Missense Mutation (SNP) | VAF 69/247 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100795485; called by muse, mutect2, varscan2
- ZCCHC2 | c.3457G>A p.A1153T | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV99502178; called by muse, mutect2, varscan2
- ZNHIT2 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV99658040; called by muse, mutect2
- LONRF3 | c.1653C>A p.N551K (on ENST00000371628 / NM_001031855.3; = p.N510K on NM_024778.5) | Missense Mutation (SNP) | VAF 18/528 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- MAP1LC3B2 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 16/548 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); called by muse, mutect2
- NFIA | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 10/313 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.171); called by muse, mutect2
- AMPD3 | c.1878G>A p.Q626= (on ENST00000396553 / NM_001025389.2; = p.Q635= on NM_000480.3) | Silent (SNP) | VAF 28/684 reads (4%) | catalogued as COSV101158102; called by muse, mutect2
- GLUD1 | c.240C>T p.I80= | Silent (SNP) | VAF 125/408 reads (31%) | catalogued as COSV53280432; called by muse, mutect2, varscan2
- PAX5 | c.879G>T p.V293= | Silent (SNP) | VAF 20/278 reads (7%) | catalogued as COSV100814083; called by muse, mutect2
- REG1B | c.351C>T p.S117= | Silent (SNP) | VAF 15/197 reads (8%) | catalogued as COSV100521265; called by muse, mutect2
- CAPN1 | chr11:65214341 G>A | 3'Flank (SNP) | VAF 25/85 reads (29%) | called by muse, mutect2, varscan2
